Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3373, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3373-01A (Primary Tumor).

[page 1 of 2]
Collected Date & Time: [REDACTED]

TCGA-A3-3373

Result Name	Results	Units	Reference Range
✓ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Gallstones, right renal mass

Post-Op Diagnosis

Nothing indicated

Clinical History

Nothing indicated

Gross Description:

Two parts

Container labeled [REDACTED] 1 - gallbladder" has an 8.0 x 3.0 x 2.5 cm previously partially opened gallbladder having a smooth gray-pink serosa. The wall measures up to 0.1 cm and is fibrotic. The lumen is lined by finely trabeculated hyperemic mucosa. Within the lumen is a moderate amount of viscid green bile, as well as several firm friable granular green-black calculi measuring individually up to 0.2 cm and measuring in aggregate 0.6 x 0.6 x 0.2 cm. Representative sections are submitted in a single cassette.

Container labeled [REDACTED] 2 - right kidney" has a 530 gram previously partially sectioned right nephrectomy specimen surrounded by a moderate amount of perinephric adipose tissue and faced anteriorly by a small amount of Gerota's fascia. The specimen overall as received is 22.8 x 11.5 x 5.1 cm. In the upper anterior medial aspect is a 2.1 x 1.5 x 1.0 cm area of fragmented chalky tan-yellow tissue grossly consistent with fragmented adrenal gland. The renal margins of resection include 1.1 cm of grossly patent renal artery, 1.3 cm of grossly patent renal vein and 5.7 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring 11.0 x 7.9 x 6.0 cm. Extending from the upper to mid pole on the lateral aspect is a 6.5 x 5.5 x 5.4 cm lobulated well circumscribed apparent unencapsulated lesion having a red-brown to chalky yellow moderately hemorrhagic cut surface. This extends beyond the plane of the renal cortex into the surrounding adipose tissue; however, it appears to be completely covered by an intact layer of attenuated cortical parenchyma. The lesion grossly appears to compress the surrounding structures and grossly approaches vascular structures near the hilus; however, the lesion does not grossly appear to extend into these structures. The remaining renal parenchyma shows a cortex measuring up to 0.7 cm which is slightly edematous but homogeneous and red-brown. The corticomedullary junction is poorly defined. The medulla is homogeneous red-brown with sharp papillae. The calyces and pelvis are lined by smooth tan-white mucosa extending into the ureter. Also received in the same container are three tissue cassettes each labeled [REDACTED] Representative sections are submitted labeled as follows: A - vascular and ureteral margins; B-G

[page 2 of 2]
- lesion and surrounding tissue; H - random uninvolved parenchyma; I
- adrenal gland.

Microscopic Description:

Reviewed are slides labeled [REDACTED]

Final Diagnosis

Gallbladder, cholecystectomy:

Chronic cholecystitis.

Cholelithiasis.

No evidence of malignancy.

Kidney, right, radical nephrectomy:

Tumor characteristics:

1. Histologic type: Conventional (clear cell) renal carcinoma
2. Tumor site: Upper to mid pole lateral right kidney
3. Tumor size: 6.5 x 5.5 x 5.4 cm
4. Macroscopic extent of tumor: Tumor limited to kidney
5. Nuclear grade: Fuhrman grade 3/4
6. Lymphovascular space invasion: Present
7. Transcapsular invasion: Not identified
8. Renal vein invasion: Not identified
9. Vena caval invasion: Not identified
10. Adrenal gland: Not involved by tumor

Surgical margin status:

1. Soft tissue margins: Free of malignancy in sections examined
2. Ureteral margin: Free of malignancy in sections examined
3. Vascular margins: Free of malignancy in sections examined

Lymph node status:

Not applicable (no lymph nodes submitted for evaluation).

Stage:

pT1b Nx Mx PAS 9 SPC-A

CPT: 88304, 88307

Comments

[REDACTED] has reviewed this case and concurs with the diagnosis.

This test has been finalized at the [REDACTED]

Electronically Signed by: # [REDACTED]

Source: NCI Genomic Data Commons file 5cff8cbb-3993-44a9-8253-1d6b6cd0d989 (TCGA-A3-3373.5C4D5028-ECF2-4302-93D0-8E20273468BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).